CCDI case PBCENX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/f92ecfda-df17-4dd5-9bdc-293846b7c5e9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 0.8 years (285 days).

Biospecimens (3 samples)
- Samples 0DQ2N6, 0DQ2NI (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ2P3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
